Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7392, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7392-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1) TONGUE, RIGHT VENTRAL, EXCISION: MODERATELY DIFFERENTIATED KERATINIZING SQUAMOUS CELL CARCINOMA; PERINEURAL INVASION PRESENT.

Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) right ventral tongue

GROSS DESCRIPTION:

1) SOURCE: Right Ventral Tongue

Received fresh in a container labeled "right ventral tongue" are two pink soft tissue fragments that in aggregate measure 1.0 cm x 0.3 cm x 0.3 cm.

The specimen is entirely submitted in cassette 1A.

Summary of sections: 1A, 2/1.

Dictated by [REDACTED])

Slides and report reviewed by Attending Pathologist.

Source: NCI Genomic Data Commons file 49da9616-5874-4f28-894b-9f26eefb4645 (TCGA-CR-7392.A5ECE60C-2AFB-47C0-9BFD-AC3F8D696EA1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).